CTSP case CTSP-AD4V — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/bd18c252-e23c-40d9-a9b0-98ebe7146f89

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Age at diagnosis: 76.9 years (28,105 days).

Biospecimens (1 sample)
- Sample DLBCL11281-sample: Sample type: Tumor; Tissue type: Tumor.
